Somatic mutation profile of tumor specimen C3N-01517-01 (aliquot CPT0167530006) from CPTAC case C3N-01517, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.9 years (18,211 days).
Specimen C3N-01517-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e60ec5a8-ca96-443a-b04b-944aee004324.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01517-71 (Blood Derived Normal), aliquot CPT0167590002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b468aa6b-8faa-4df7-bf0e-49e5ac8506d7

The open-access MAF lists 52 somatic variants for this specimen: 40 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 10, Intron 2, Splice Site 2, Frame Shift Ins 2, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.322A>G p.R108G | Missense Mutation (SNP) | VAF 157/1638 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519888, COSV51812540; ClinVar: likely pathogenic; called by muse, mutect2
- ABCC9 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 9/251 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs886039121, COSV53976492; ClinVar: uncertain significance; called by muse, mutect2
- ANK1 | c.4001G>A p.R1334Q | Missense Mutation (SNP) | VAF 184/480 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs142517120, COSV99225196; called by muse, mutect2, varscan2
- CACNA1H | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs374558503, COSV61984948; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA2D4 | c.1885G>A p.V629I | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as rs1314831440; called by muse, mutect2, varscan2
- CALCR | c.1357G>A p.D453N (on ENST00000649521 / NM_001164737.2; = p.D437N on NM_001742.4) | Missense Mutation (SNP) | VAF 87/259 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs530931616, COSV64008410; called by muse, mutect2, varscan2
- CHRM2 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 99/356 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as rs147228075; called by muse, mutect2, varscan2
- CRB2 | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.009); catalogued as rs779153310; called by muse, mutect2
- DPP10 | c.1246C>T p.R416W | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772658327, COSV59665250; called by muse, mutect2, varscan2
- GPR179 | c.2174C>T p.A725V (on ENST00000621958; = p.A724V on NM_001004334.4) | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.441); catalogued as rs376647969; called by muse, mutect2, varscan2
- HCN1 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 78/118 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100300089; called by muse, mutect2, varscan2
- LYNX1 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 96/275 reads (35%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); catalogued as rs764854150, COSV100235436; called by muse, mutect2, varscan2
- NKX6-1 | c.566G>C p.R189P | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV99879902; called by muse, varscan2
- NR1H2 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as rs758378065, COSV53800906; called by muse, mutect2, varscan2
- OR2L3 | c.659T>A p.V220D | Missense Mutation (SNP) | VAF 95/293 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63455506; called by muse, mutect2, varscan2
- PLEKHG2 | c.2383G>T p.D795Y | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV52687668; called by muse, mutect2
- POLR2D | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV55759546; called by muse, mutect2
- RAD50 | c.3538C>T p.R1180W | Missense Mutation (SNP) | VAF 133/348 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1333645178; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RTN1 | c.636C>A p.H212Q | Missense Mutation (SNP) | VAF 64/153 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.025); catalogued as rs769959164; called by muse, mutect2, varscan2
- SPANXN3 | c.38C>T p.T13M | Missense Mutation (SNP) | VAF 74/100 reads (74%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs201331560, COSV65140481; called by muse, varscan2
- THNSL2 | c.569G>C p.G190A | Missense Mutation (SNP) | VAF 53/145 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1298391546; called by muse, mutect2, varscan2
- TMC3 | c.2697dup p.H900Tfs*17 | Frame Shift Ins (INS) | VAF 50/135 reads (37%) | catalogued as rs776122233; called by mutect2, pindel, varscan2
- ADGRV1 | c.426T>A p.N142K | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANGPTL2 | c.1208A>G p.N403S | Missense Mutation (SNP) | VAF 120/304 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- ANO8 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- CACNB1 | c.1736C>A p.P579Q | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CDH9 | c.644-2A>T p.X215_splice | Splice Site (SNP) | VAF 40/108 reads (37%) | called by muse, varscan2
- DNAI3 | c.892A>G p.N298D | Missense Mutation (SNP) | VAF 88/174 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- FRG1BP | n.523-1G>C | Splice Site (SNP) | VAF 52/174 reads (30%) | called by muse, mutect2, varscan2
- KLF1 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 97/331 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KSR2 | c.1577C>T p.S526F | Missense Mutation (SNP) | VAF 76/199 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAVS | c.1240del p.S416Rfs*3 | Frame Shift Del (DEL) | VAF 88/339 reads (26%) | called by mutect2, pindel, varscan2
- NPAT | c.1375del p.S459Lfs*25 | Frame Shift Del (DEL) | VAF 114/316 reads (36%) | called by mutect2, pindel, varscan2
- SERPINB11 | c.121A>C p.M41L | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- SESN3 | c.434T>G p.L145W | Missense Mutation (SNP) | VAF 85/225 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC18A1 | c.473dup p.L160Sfs*62 | Frame Shift Ins (INS) | VAF 25/72 reads (35%) | called by mutect2, pindel, varscan2
- TENM1 | c.1814G>T p.G605V | Missense Mutation (SNP) | VAF 98/123 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.45840C>A p.D15280E (on ENST00000591111; = p.D7856E on NM_003319.4) | Missense Mutation (SNP) | VAF 202/463 reads (44%) | PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ZNF215 | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 43/128 reads (34%) | called by muse, mutect2, varscan2
- ZNF614 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 67/318 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AQP12A | c.237G>A p.S79= | Silent (SNP) | VAF 159/422 reads (38%) | catalogued as rs151095143, COSV100538937; called by muse, varscan2
- C6orf52 | c.153C>T p.H51= | Silent (SNP) | VAF 83/245 reads (34%) | catalogued as rs746914088; called by muse, mutect2, varscan2
- GFM2 | c.1437A>G p.L479= | Silent (SNP) | VAF 161/397 reads (41%) | called by muse, mutect2, varscan2
- HYDIN | c.4488C>T p.L1496= | Silent (SNP) | VAF 44/108 reads (41%) | catalogued as rs191482082, COSV66834816; called by muse, mutect2
- LAMC2 | c.945C>T p.Y315= | Silent (SNP) | VAF 77/202 reads (38%) | called by muse, mutect2, varscan2
- PAPLN | c.2034C>T p.H678= (on ENST00000554301; = p.H651= on NM_173462.4) | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs374698062; called by muse, mutect2
- RAB11FIP1 | c.1023C>A p.S341= | Silent (SNP) | VAF 90/231 reads (39%) | called by muse, mutect2, varscan2
- REPS1 | c.1500G>A p.S500= | Silent (SNP) | VAF 39/115 reads (34%) | catalogued as rs1454474612, COSV57809571; called by muse, mutect2, varscan2
- RGMA | c.384G>A p.T128= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as rs1171718224; called by muse, mutect2, varscan2
- RSPH6A | c.1158G>A p.A386= | Silent (SNP) | VAF 72/270 reads (27%) | catalogued as rs150763678, COSV99679861; called by muse, mutect2, varscan2
- GPD1 | c.360+201C>T | Intron (SNP) | VAF 71/166 reads (43%) | catalogued as rs1178890658; called by muse, mutect2
- MAP2 | c.5074-2067A>G | Intron (SNP) | VAF 68/176 reads (39%) | called by muse, mutect2, varscan2
